Somatic mutation profile of tumor specimen TCGA-ZM-AA06-01A (aliquot TCGA-ZM-AA06-01A-12D-A435-10) from TCGA case TCGA-ZM-AA06, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 45.8 years (16,719 days).
Specimen TCGA-ZM-AA06-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20354e29-a4ce-4251-be4a-4a5ad99b3c5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA06-10A (Blood Derived Normal), aliquot TCGA-ZM-AA06-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b1d04a-d4c7-4736-8acb-d4a934ec33ce

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, In Frame Del 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1228-2A>G p.X410_splice | Splice Site (SNP) | VAF 44/85 reads (52%) | catalogued as rs727504426, CS099551, COSV50629953, COSV50663791; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FAM98C | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs200637370, COSV53039684; called by mutect2, varscan2
- IFT140 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs369998823; called by muse, mutect2, varscan2
- PLIN5 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV67851165; called by muse, mutect2, varscan2
- ZWILCH | c.53+7C>G | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as rs767749878; called by muse, mutect2, varscan2
- ATR | c.6611T>C p.M2204T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CELSR1 | c.8011G>A p.G2671R | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 49/115 reads (43%) | called by muse, mutect2, varscan2
- FGD1 | c.2141A>T p.N714I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- HUWE1 | c.7953G>A p.W2651* | Nonsense Mutation (SNP) | VAF 66/161 reads (41%) | called by muse, mutect2, varscan2
- NDST1 | c.1266_1268del p.T423del | In Frame Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- PLIN5 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- UBQLN1 | c.462del p.A156Qfs*3 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, varscan2
- UBQLN1 | c.461del p.G154Dfs*5 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2*, pindel, varscan2*
- BAZ2A | c.3603A>G p.Q1201= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- CHCHD6 | c.456C>T p.D152= | Silent (SNP) | VAF 25/84 reads (30%) | called by muse, varscan2
- DMGDH | c.673A>C p.R225= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- IRX2 | c.348G>A p.A116= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57413828; called by muse, mutect2, varscan2
- ZNF146 | c.345C>T p.L115= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs369142601; called by muse, mutect2, varscan2
- TP63 | c.1350-6247C>G | Intron (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- ZNF219 | chr14:21103093 del CCTTTCTCAC | 5'Flank (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
